Somatic mutation profile of tumor specimen TCGA-KL-8336-01A (aliquot TCGA-KL-8336-01A-11D-2310-10) from TCGA case TCGA-KL-8336, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 51.5 years (18,821 days).
Specimen TCGA-KL-8336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b81ea960-f348-454a-8c49-8a421eb44366.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8336-11A (Solid Tissue Normal), aliquot TCGA-KL-8336-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b99cfe6c-b4e6-443b-a292-8fd7cfe78803

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 56/73 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.7187G>A p.R2396K (on ENST00000272895 / NM_173076.3; = p.R2078K on NM_015657.3) | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55960241; called by mutect2, varscan2
- CROT | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV100519535; called by muse, mutect2, varscan2
- DAAM2 | c.2729T>C p.V910A (on ENST00000274867 / NM_001201427.2; = p.V909A on NM_015345.3) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV51333493; called by muse, mutect2, varscan2
- GSN | c.1865T>C p.L622P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100376621; called by muse, mutect2, varscan2
- IFI16 | c.2261T>C p.I754T (on ENST00000295809 / NM_001364867.2; = p.I698T on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV99858256; called by muse, mutect2
- KRT84 | c.1424+1G>A p.X475_splice | Splice Site (SNP) | VAF 29/64 reads (45%) | catalogued as COSV99231067; called by muse, mutect2, varscan2
- MGA | c.2911C>T p.R971W | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs372252914; called by muse, mutect2, varscan2
- NCAPH | c.2002A>G p.N668D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.138); catalogued as COSV99546234; called by muse, mutect2, varscan2
- OR2C3 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100825801; called by muse, varscan2
- OR52L1 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1166826123, COSV100176373; called by muse, mutect2
- PER3 | c.2247C>G p.D749E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.202); catalogued as rs201449626, COSV62707580; called by muse, mutect2, varscan2
- QRICH1 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as COSV100676992; called by muse, mutect2, varscan2
- USP54 | c.229T>G p.C77G | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100161442; called by muse, mutect2, varscan2
- ZNF836 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 81/202 reads (40%) | catalogued as COSV100441358; called by muse, mutect2, varscan2
- PTEN | c.582_584del p.L194del | In Frame Del (DEL) | VAF 32/42 reads (76%) | called by pindel, varscan2
- DSC3 | c.231G>T p.G77= | Silent (SNP) | VAF 80/101 reads (79%) | catalogued as COSV100844754, COSV64571555; called by muse, mutect2, varscan2
- FAT4 | c.6978A>C p.T2326= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100630391; called by muse, mutect2
- TRIM3 | c.1194G>T p.L398= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100624554; called by muse, mutect2, varscan2
